Somatic mutation profile of tumor specimen TARGET-10-PARVHY-09A (aliquot TARGET-10-PARVHY-09A-01D) from TARGET case TARGET-10-PARVHY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.7 years (5,718 days).
Specimen TARGET-10-PARVHY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ab15534-3ac3-473d-ae9b-e20e5f666e3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARVHY-10A (Blood Derived Normal), aliquot TARGET-10-PARVHY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bcf8fda-b3ed-4824-a449-9b1113b98df4

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 3'UTR 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EEF2 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs866753926, COSV100500635; called by muse, mutect2, varscan2
- FAT1 | c.7277A>T p.Q2426L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV71676705; called by muse, mutect2, varscan2
- FOXRED1 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV55009490; called by muse, mutect2, varscan2
- POLN | c.2299G>A p.V767M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as rs749012576, COSV67028402; called by muse, mutect2, varscan2
- VPS36 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as COSV65200411; called by muse, mutect2, varscan2
- IGHA2 | c.389C>A p.A130E | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB1 | c.165C>A p.N55K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.197); called by muse, mutect2
- CCDC8 | c.936G>A p.R312= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1225777893; called by muse, mutect2, varscan2
- HERC4 | c.243G>T p.L81= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV53273332; called by muse, mutect2
- SYNE3 | c.1713C>T p.V571= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV62083209; called by muse, mutect2, varscan2
- CFL2 | c.*635G>T | 3'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- TBC1D14 | c.1446+889C>A | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- VCX3A | c.*23C>A | 3'UTR (SNP) | VAF 10/65 reads (15%) | catalogued as rs1169238297; called by muse, varscan2
